Surgical pathology report (de-identified scan), TCGA case TCGA-34-A5IX, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-A5IX-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIB, FIFTH, EXCISION—

- BENIGN BONE AND BONE MARROW WITH TRILINEAGE HEMATOPOIESIS.
- NEGATIVE FOR MALIGNANCY

PART 2: LYMPH NODE, LEVEL 11, EXCISION:

ONE (1) ANTHRACOSILICOTIC LYMPH NODE, NEGATIVE FOR MALIGNANCY, (0/1).

PART 3: LUNG, RIGHT LOWER LOBE, LOBECTOMY—

- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 6.7 X 5.5 X 4.7 CM.
- LYMPHOVASCULAR INVASION PRESENT.
- VISCERAL PLEURAL INVASION SEEN BY ELASTIC STAINS (PL3) (SEE COMMENT).
- CARCINOMA INVADERS THE DIAPHRAGM.
- BRONCHOVASCULAR MARGINS NEGATIVE FOR MALIGNANCY.
- DIAPHRAGM SOFT TISSUE MARGINS NEGATIVE FOR MALIGNANCY.
- TEN (10) ANTHRACOSILICOTIC PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR MALIGNANCY, (0/10).
- NON-NEOPLASTIC LUNG WITH ORGANIZING PNEUMONIA.
- ORGANIZING THROMBUS WITH RECANALIZATION PRESENT WITHIN PULMONARY ARTERY.
- AJCC 7TH EDITION PATHOLOGIC TUMOR STAGE: pT3N0 AND HISTOLOGIC GRADE 2.

PART 4: LUNG, RIGHT MIDDLE LOBE, LOBECTOMY—

- LUNG PARENCHYMA WITH MILD EMPHYSEMATOUS CHANGES AND INTRALVEOLAR PIMENTED MACROPHAGES; NEGATIVE FOR MALIGNANCY.
- BRONCHOVASCULAR MARGINS NEGATIVE FOR MALIGNANCY.
- ONE (1) ANTHRACOSILICOTIC PERIBRONCHIAL LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 5: LYMPH NODE, LEVEL 4, EXCISION:

FOUR (4) ANTHRACOSILICOTIC LYMPH NODES, NEGATIVE FOR MALIGNANCY, (0/4).

PART 6: LYMPH NODE, LEVEL 10, EXCISION:

ONE (1) ANTHRACOSILICOTIC LYMPH NODE, NEGATIVE FOR MALIGNANCY, (0/1).

PART 7: LYMPH NODE, LEVEL 7, EXCISION:

TWO (2) ANTHRACOSILICOTIC LYMPH NODES, NEGATIVE FOR MALIGNANCY, (0/2).

ICD-6-3
Carcinoma, Squamous cell NOS
8070/3
Site R Lung, lower lobe
C34.3
JW 3/28/13

COMMENT:

Immunohistochemical and special stains are performed with adequate controls and demonstrate that the tumor cells are positive for CK5/6 and p63 and negative for CK7, TTF-1, PAS-D and mucicarmine, supporting the above diagnosis. An elastic stain highlights tumor invading through the visceral pleura into the fibrous tissue of the diaphragm. Ancillary studies will be performed on block 3F and the results issued as an addendum.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION:	Right Middle Lobe (should be lower lobe - no malignancy found in middle lobe.)
PROCEDURE:	Lobectomy
TUMOR SIZE:	Maximum dimension: 6.7 cm Minor dimension: 5.5 cm
TUMOR TYPE:	Invasive squamous carcinoma, peripheral type
HISTOLOGIC GRADE:	G2, Moderately differentiated
EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:	Parietal pleura (PL3) Diaphragm
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	No
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 13
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 6
T STAGE, PATHOLOGIC:	pT3
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	Not applicable
ANCILLARY STUDIES:	Histochemical stains, Immunohistochemical stains, FISH studies, Molecular studies

Diagnostic Discrepancy		✓
HPV Discrepancy		✓

Source: NCI Genomic Data Commons file 9f2dea70-7fcf-4abf-b040-c86c4b71b513 (TCGA-34-A5IX.7DFC893F-4AA7-4885-B2D3-AF0203ED536A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).